Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72N, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72N-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

ICD-3
Carcinoma, renal cell
chromophobe type 8817/3
Site @ Kidney NGS
C64.9
GND 8/9/13

Diagnosis:

A. Kidney, left, partial nephrectomy

Histologic tumor type/subtype: chromophobe renal cell carcinoma

Sarcomatoid features: not identified

Histologic grade (if applicable): not applicable

Tumor size (greatest dimension): 3.8 cm by gross examination

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: not identified

Gerota' s fascia: not applicable

Renal sinus: not identified

Major veins (renal vein or segmental branches, IVC): not identified

Ureter: not applicable

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): negative

Renal capsular margin (partial nephrectomy only): negative

Perinephric adipose tissue margin (partial nephrectomy only): negative

Adrenal gland: not submitted

Lymph nodes: none identified

Other significant findings: none

AJCC Staging: pT1a pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

[page 2 of 3]
Comment:

Special stains support the diagnosis. The tumor demonstrates positive staining for Hale's colloidal iron, CK7 and CD117. The tumor cells are negative for vimentin, CD10, CD15 and RCC. Appropriate controls are performed.

Clinical History:

The patient is a -year-old man with an incidentally discovered renal mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: partial nephrectomy

Side of specimen: left

Size and weight of specimen: 33 grams, 4.8 x 4.6 x 3.6 cm; There is also a black stitch to mark the tumor capsule, focally ruptured during extraction.

Orientation: The fat overlying the kidney capsule is inked blue. The parenchymal margin is inked black.

Presence/absence of adrenal gland: absent

Tumor site: Cortex

Tumor description: The tumor is a solid, tan, well circumscribed mass. The tumor abuts the renal capsule and is less than 0.1 cm from the fat overlying the capsule (blue margin), and 0.1 cm from the parenchymal margin (inked black).

Tumor size: 3.8 x 3.4 x 0.2 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: Confined; the mass appears to be grossly abutting the capsule but is confined to kidney.

Extent of invasion:

Perirenal adipose tissue: does not involve

Gerota' s fascia: n/a

[page 3 of 3]
Renal vein: n/a

Ureter: n/a

Renal Sinus: no evidence of invasion

Pelvic/Caliceal: n/a

Adrenal: n/a

Other organs: n/a

Surgical margins:

Perirenal adipose tissue: The tumor is less than 0.1 cm from the blue inked margin.

Renal vein: n/a

Renal artery: n/a

Ureter: n/a

Description of kidney away from tumor: There is little uninvolved kidney parenchyma present. The tumor is present primarily within the cortex with limited portions of medulla evident, the renal parenchyma is tan/brown and firm.

Hilar lymph nodes: n/a

Other significant findings: There is a 7.9 x 5.5 x 0.9 cm additional fragment of adipose tissue received separately in the container, and is grossly unremarkable.

Tissue submitted for

Tissue to

Digital picture: no

Block summary:

A1,A2 - mass with closest distance to parenchymal margin (inked black)

A3,A4 - mass with closest distance to fat overlying capsule and capsule (inked blue)

A5 - representative normal with mass

A6 - representative additional free floating fat

Dx./Synchronous Primary No.		

Source: NCI Genomic Data Commons file 445b3b84-b7bb-48dc-ad03-c2d6655112de (TCGA-UW-A72N.A34F4767-2755-4E12-884C-A8DD949AD1F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).